TARGET case TARGET-20-ML1 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/cff2c842-b9cd-4aa4-9923-9ab701d847e0

Biospecimens (1 sample)
- Sample TARGET-20-ML1-50A: Sample type: Cell Lines; Tissue type: Tumor; Specimen type: Derived Cell Line.
